Somatic mutation profile of tumor specimen TARGET-10-PATDMN-09A (aliquot TARGET-10-PATDMN-09A-01D) from TARGET case TARGET-10-PATDMN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,526 days).
Specimen TARGET-10-PATDMN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71676553-ec98-48a3-b208-dc7a5ea5d878.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDMN-10A (Blood Derived Normal), aliquot TARGET-10-PATDMN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/860e92e6-4545-4646-bc9f-de223d77d3e1

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 4, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FKTN | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs119463990, CM980740, COSV56313039; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYP2C9 | c.890C>G p.A297G | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV53254352; called by muse, mutect2, varscan2
- ESRP2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs1250892802, COSV52177122; called by muse, mutect2, varscan2
- FBXO28 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV64800209; called by muse, mutect2, varscan2
- FMO4 | c.464T>G p.L155* | Nonsense Mutation (SNP) | VAF 57/127 reads (45%) | catalogued as COSV63002168; called by muse, mutect2, varscan2
- HYLS1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749875301, COSV54989340; called by muse, mutect2, varscan2
- IFT172 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs202089120; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, mutect2, varscan2
- PITPNM2 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54911208; called by muse, mutect2, varscan2
- PPP2R2D | c.981G>C p.E327D | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV70780027; called by muse, mutect2, varscan2
- SCIMP | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV68311508; called by muse, mutect2, varscan2
- SCRN3 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC27A1 | c.1256_1257insGCGTACCCCAT p.I419Mfs*8 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, varscan2
- UTY | c.2916C>G p.S972R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- AL356585.2 | n.824C>T | RNA (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
